Somatic mutation profile of tumor specimen TARGET-10-PARACE-09A (aliquot TARGET-10-PARACE-09A-01D) from TARGET case TARGET-10-PARACE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.8 years (2,468 days).
Specimen TARGET-10-PARACE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d52d7b04-c9c0-4b75-9f89-10dd107c19d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARACE-10A (Blood Derived Normal), aliquot TARGET-10-PARACE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ee4dd2f-eec2-47ee-91b6-785e00a252a4

The open-access MAF lists 40 somatic variants for this specimen: 24 protein-altering or splice-affecting, 11 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 11, Intron 4, RNA 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 19/70 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 4/39 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- ADGRB2 | c.3082C>T p.R1028W | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1176235358; called by muse, mutect2, varscan2
- CSRNP3 | c.1082C>T p.T361M | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs543669496, COSV58775683; called by muse, mutect2, varscan2
- GRIK2 | c.2243G>A p.R748Q | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs767506745, COSV59721309; called by muse, mutect2
- KCNT1 | c.1036C>T p.R346C (on ENST00000488444; = p.R365C on NM_020822.3) | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs751116785, COSV53708577; called by muse, mutect2, varscan2
- KIAA1958 | c.2035C>T p.R679W | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs771772720; called by muse, mutect2
- MEIS2 | c.1174G>A p.V392I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); catalogued as rs151055354; called by muse, mutect2, varscan2
- MROH5 | c.92del p.P31Lfs*6 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | catalogued as rs748849454; called by mutect2, pindel, varscan2
- MYO3B | c.4010C>A p.S1337Y | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV58701205; called by muse, mutect2
- NAV3 | c.4004C>T p.S1335L | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs775821161, COSV57067426; called by muse, mutect2, varscan2
- PCDHB9 | c.682A>G p.I228V | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs374862339; called by muse, mutect2, varscan2
- POLR3E | c.1066G>A p.V356I | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.125); catalogued as rs372913863; called by muse, mutect2, varscan2
- SCARA5 | c.1006G>A p.G336R | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1022398722; called by muse, mutect2, varscan2
- SLC39A4 | c.803C>T p.T268M (on ENST00000301305 / NM_001374839.1; = p.T243M on NM_017767.3) | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); catalogued as rs185494598, COSV52778661; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNN | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs769956022; called by muse, mutect2, varscan2
- CMYA5 | c.9176T>C p.I3059T | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CRYBG3 | c.1431G>T p.K477N | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); called by muse, mutect2
- IGLV4-69 | chr22:22031464 del TGGCATTCACACA | Missense Mutation (DEL) | VAF 12/54 reads (22%) | called by mutect2, pindel*, varscan2
- KSR2 | c.2653C>A p.Q885K | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OSER1 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- VEGFD | c.530A>T p.E177V | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- XPNPEP2 | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.98); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- ZFHX4 | c.5101G>T p.E1701* | Nonsense Mutation (SNP) | VAF 20/179 reads (11%) | called by muse, mutect2, varscan2
- ALKBH3 | c.774A>T p.R258= | Silent (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- ARID3A | c.1680C>T p.N560= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs751013219; called by muse, mutect2, varscan2
- DCC | c.4077G>A p.P1359= | Silent (SNP) | VAF 58/120 reads (48%) | catalogued as rs571287631, COSV71432561; called by muse, mutect2, varscan2
- DST | c.6813A>T p.I2271= | Silent (SNP) | VAF 18/150 reads (12%) | called by muse, mutect2, varscan2
- GRM4 | c.252C>T p.F84= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as rs763571105, COSV100946865, COSV65215701; called by muse, mutect2, varscan2
- HOXB3 | c.831C>T p.N277= | Silent (SNP) | VAF 6/104 reads (6%) | catalogued as rs1464006754, COSV100290687; called by muse, mutect2
- MYH13 | c.4323C>T p.T1441= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as rs779258921, COSV52820047; called by muse, mutect2, varscan2
- MYH7 | c.4908C>T p.A1636= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs150241539; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- RTL4 | c.885C>A p.A295= | Silent (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- RYR3 | c.5838G>A p.T1946= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as rs757689158, COSV66778808, COSV66810292; called by muse, mutect2, varscan2
- UNC13B | c.4713C>T p.D1571= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs752369679; called by muse, mutect2
- AL590867.2 | n.53G>A | RNA (SNP) | VAF 29/75 reads (39%) | catalogued as rs776253514; called by muse, mutect2, varscan2
- CDH1 | c.687+104G>A | Intron (SNP) | VAF 4/10 reads (40%) | called by muse, varscan2
- MAST4 | c.675-49337G>A | Intron (SNP) | VAF 7/112 reads (6%) | called by muse, mutect2
- PTCH1 | c.3550-17G>A | Intron (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- RNH1 | c.443+46C>T | Intron (SNP) | VAF 8/25 reads (32%) | called by muse, varscan2
